Gene-level copy-number profile of tumor specimen BLGSP-71-08-00033-01B from CGCI case BLGSP-71-08-00033, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 8.5 years (3,111 days).
Specimen BLGSP-71-08-00033-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3625d592-e5d6-4350-8329-e1d3ffb95eb5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00033-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,758 have no estimate.
https://portal.gdc.cancer.gov/files/56ba391e-1d39-498e-8150-728c1fde1a45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,499; copy number 2: 52,402; copy number 3: 2,775; copy number 4: 103; copy number 5: 43; copy number 6: 16; copy number 7: 5; copy number 8: 5; copy number 9: 2; copy number 10: 2; copy number 12: 6; copy number 21: 1; copy number 22: 1; copy number 44: 3; copy number 135: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,234,812–90,315,836, 3 genes, copy number 6–9: IGKV3D-7, AC233263.2, IGKV1OR2-118.
- chr2:91,723,023–91,723,605, 1 gene, copy number 5: NKAIN1P2.
- chr5:70,025,247–71,025,339, 19 genes, copy number 5–135: SERF1B, SMN2, AC140134.1, NAIPP2, CDH12P3, AC138866.1, GUSBP14, GTF2H2B, AC146944.2, NAIPP1, AC146944.1, GUSBP15, GUSBP16, AC139272.1, CDH12P1, SERF1A, SMN1, AC139834.1, NAIP.
- chr5:71,074,225–71,093,193, 1 gene, copy number 6: OCLNP1.
- chr5:71,197,646–71,259,238, 2 genes, copy number 5: GUSBP9, GUSBP17.
- chr8:7,926,337–7,952,413, 2 genes, copy number 8: ZNF705B, DEFB108A.
- chr8:7,976,393–7,977,985, 1 gene, copy number 5 (within-gene range 2–5): USP17L3.
- chr9:64,369,394–64,413,142, 2 genes, copy number 6: ANKRD20A4P, RNU6-1193P.
- chr9:64,621,560–64,765,535, 5 genes, copy number 5: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr15:43,599,563–43,618,800, 1 gene, copy number 12 (within-gene range 2–12): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 12 (within-gene range 2–12): AC011330.3.
- chr15:43,663,654–43,684,339, 1 gene, copy number 22 (within-gene range 2–22): AC011330.1.
- chr16:32,356,981–32,380,049, 2 genes, copy number 12: AC133548.1, ACTR3BP3.
- chr16:32,882,586–32,888,874, 1 gene, copy number 7 (within-gene range 1–7): AC142086.1.
- chr21:7,744,962–8,680,934, 27 genes, copy number 5–21: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, CR381572.2.
- chr21:12,999,676–13,120,807, 5 genes, copy number 5–10: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:13,644,775–13,777,266, 10 genes, copy number 6: MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1.
- chr22:18,361,820–18,391,105, 2 genes, copy number 7: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
